TCGA case TCGA-16-0846 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Toronto Western Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/543c0a7d-ccd7-4b8d-98fb-eabec806231d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 85 years; Vital status: Dead; Days to death: 119 days.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 85.2 years (31,111 days); Year of diagnosis: 2006; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 119 days; Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-16-0846-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2; Intermediate dimension: 0.7; Shortest dimension: 0.5.
  Slide TCGA-16-0846-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 85; Percent normal cells: 10; Percent necrosis: 5; Percent stromal cells: 5.
  Slide TCGA-16-0846-01A-01-TS2: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 5.
- Sample TCGA-16-0846-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 119 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 119 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 119 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-16-0846-01A-01D-0384-01): tumor purity 0.64, ploidy 3.72, whole-genome doublings 1.
